Gene-level copy-number profile of tumor specimen TCGA-25-1312-01A from TCGA case TCGA-25-1312, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.9 years (25,537 days).
Specimen TCGA-25-1312-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ab0cc4c2-aa3b-4c0c-904e-090c5ce00162.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1312-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11503fa6-c4ce-4c01-a1a3-e6c5169f8b4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,467; copy number 2: 18,366; copy number 3: 15,809; copy number 4: 13,171; copy number 5: 8,017; copy number 6: 1,243; copy number 7: 10; copy number 8: 126; copy number 10: 85; copy number 12: 42; copy number 13: 129; copy number 14: 163; copy number 18: 20; copy number 21: 96; copy number 24: 64; copy number 28: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-1312-01A-01D-0452-01): tumor purity 0.82, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,997 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,785,285–2,323,085, 15 genes, copy number 5 (within-gene range 4–5): GNB1, AL109917.1, CALML6, TMEM52, CFAP74, AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3.
- chr1:2,326,201–2,326,693, 1 gene, copy number 5: AL589739.1.
- chr1:26,529,761–28,546,542, 96 genes, copy number 6 (broad region; genes not listed).
- chr2:28,384,409–28,664,540, 8 genes, copy number 5 (within-gene range 4–5): FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1.
- chr2:36,299,388–36,299,830, 1 gene, copy number 5: RPL21P36.
- chr2:76,445,079–83,657,842, 62 genes, copy number 5 (broad region; genes not listed).
- chr3:89,107,621–117,139,389, 321 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:116,850,277–198,222,513, 1,483 genes, copy number 5–6 (broad region; genes not listed).
- chr5:147,824,572–149,129,578, 30 genes, copy number 13: SPINK1, AC011352.2, SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145.
- chr6:151,615,773–151,615,879, 1 gene, copy number 5: RNU6-813P.
- chr7:70,972–2,476,894, 69 genes, copy number 5 (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 5 (broad region; genes not listed).
- chr8:78,516,340–81,165,266, 54 genes, copy number 5–7: PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1.
- chr8:104,981,164–114,791,929, 83 genes, copy number 5–6 (broad region; genes not listed).
- chr8:128,150,116–145,066,685, 320 genes, copy number 5–6 (broad region; genes not listed).
- chr11:34,049,967–35,420,063, 25 genes, copy number 5: AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1.
- chr11:119,364,359–119,526,664, 1 gene, copy number 5 (within-gene range 4–5): USP2-AS1.
- chr11:119,402,792–119,919,996, 14 genes, copy number 5: AP003396.2, AP003396.4, THY1, THY1-AS1, DUXAP5, KRT8P7, AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1, AP003390.1, AP001994.1, AP001994.2, AP001994.3.
- chr12:66,767–15,602,175, 529 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:18,080,869–23,251,499, 75 genes, copy number 5–6 (broad region; genes not listed).
- chr12:23,637,973–23,638,487, 1 gene, copy number 5: AC087260.1.
- chr12:25,108,289–31,616,439, 137 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:46,183,063–46,876,784, 11 genes, copy number 6 (within-gene range 4–6): SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1.
- chr12:49,568,218–49,644,666, 1 gene, copy number 5 (within-gene range 4–5): PRPF40B.
- chr12:49,619,334–53,467,528, 175 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:56,230,049–56,636,816, 27 genes, copy number 6 (within-gene range 4–6): SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A.
- chr13:26,132,115–114,337,626, 1,189 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:46,469,341–49,281,838, 71 genes, copy number 6 (broad region; genes not listed).
- chr17:27,456,470–27,626,438, 1 gene, copy number 5 (within-gene range 4–5): KSR1.
- chr17:27,526,386–29,204,474, 116 genes, copy number 5–21 (broad region; genes not listed).
- chr17:34,479,272–35,189,345, 22 genes, copy number 18–28 (within-gene range 2–28): AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4.
- chr17:37,798,894–39,204,840, 64 genes, copy number 24 (broad region; genes not listed).
- chr19:12,576,100–19,273,391, 377 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr19:23,897,321–32,676,597, 108 genes, copy number 6–10 (broad region; genes not listed).
- chr19:35,124,513–47,048,624, 645 genes, copy number 6–13 (within-gene range 3–13) (broad region; genes not listed).
- chr19:51,426,347–58,605,223, 554 genes, copy number 5–6 (broad region; genes not listed).
- chr20:3,043,622–9,839,076, 129 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:11,608,436–64,313,132, 1,204 genes, copy number 5 (broad region; genes not listed).
- chr21:15,928,296–16,645,467, 1 gene, copy number 5 (within-gene range 4–5): MIR99AHG.
- chr21:16,121,310–18,858,276, 40 genes, copy number 5: RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
